Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6332, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6332-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

TCGA - G9 - 6332

DIAGNOSIS:

- A. RIGHT PELVIC LYMPH NODES, EXCISION:
- NO TUMOR SEEN IN THREE LYMPH NODES (0/3)
- B. LEFT PELVIC LYMPH NODES, EXCISION:
- NO TUMOR SEEN IN FOUR LYMPH NODES (0/4)
- C. PROSTATE, RADICAL PROSTATECTOMY:
- ADENOCARCINOMA INVOLVING RIGHT, LEFT, ANTERIOR, POSTERIOR, BASAL, AND APICAL ASPECTS AND 40% OF THE PROSTATE
- GLEASON GRADE 4+3 (SCORE 7/10)
- PERIPROSTATIC FAT INVOLVEMENT PRESENT
- SURGICAL MARGIN NEGATIVE FOR CARCINOMA
- SEE TEMPLATE

PROSTATECTOMY TEMPLATE

Tumor type:	Adenocarcinoma
Location:	Right, left, anterior, posterior, basal, and apical
Multicentricity:	Yes
% Gland Involved:	40%
Gleason Grade/Sum:	Grade 4+3 (7/10)
High Grade PIN present:	Yes
Perineural invasion:	Yes (intraprostatic and extraprostatic)
Lymphovascular Invasion:	No
Seminal Vesicles Involved:	No (focal extraprostatic perineural invasion adjacent to the base of right seminal vesicle)
Periprostatic Fat Involved:	Yes (left)
Post Hormonal Therapy Change:	No
Margins Involved:	No
Frozen Performed:	No
Lymph Node Status:	Negative (0/3 right, 0/4 left)
Other pathologic findings:	BPH
Pathologic stage:	pT3a N0 Mx

Verbal report was given to Dr. on [REDACTED]

SPECIMEN(S):

A. RIGHT PELVIC LYMPH NODES B. LEFT PELVIC LYMPH NODES C. PROSTATE

CLINICAL HISTORY:

Not given

GROSS DESCRIPTION:

A. RIGHT PELVIC LYMPH NODES

Received in formalin are three fragments of tan yellow soft and slightly firm tissue measuring in aggregate 4.0x4.0x1.5cm. Three presumptive lymph nodes are identified. They are submitted in toto in A1-A3 (Each cassette contains one lymph node).

B. LEFT PELVIC LYMPH NODES

Received in formalin are multiple fragments of tan pink soft and slightly firm tissue measuring in aggregate 3.5x3.0x2.5cm. There are three presumptive lymph nodes identified. They are submitted in toto in B1-B2.

C. PROSTATE

Received fresh is a prostatectomy specimen weighing 35gm and measuring 5.5x4.3x3.5cm. The specimen is inked as follows: apex-red, anterior-orange, base-blue, left lateral-yellow, right lateral-green and posterior-black. The specimen is divided into to 3 levels to reveal white solid tumor areas

[page 2 of 2]
present in the posterior left and right lobes. The right seminal vesicle measures 2.8x1.5cm, the right vas deferens 2.0x0.6cm, the left seminal vesicle 2.7x1.0cm, and the left vas deferens 1.9x0.5cm. One core of the tumor and one section of the seminal vesicle are submitted for tissue procurement. The prostate is submitted as follows:

- C1-C3: apex
- C4-C5: level 1 right and left
- C6-C7: level 2 right and left
- C8-C9: level 3 right anterior and posterior
- C10-C11: level 3 left anterior and posterior
- C12-C13: right base
- C14-C15: left base
- C16-C17: right seminal vesicle
- C18-C19: left seminal vesicle
-

Source: NCI Genomic Data Commons file e3a1f9d0-c820-4233-8404-80b6cd3a604a (TCGA-G9-6332.18B9FDA1-2D69-4C5E-94BA-BFBBCD742BDD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).